Somatic mutation profile of tumor specimen ALCH-ABIM-TTP1-A (aliquot ALCH-ABIM-TTP1-A-2-0-D-A487-36) from ALCHEMIST case ALCH-ABIM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,298 days).
Specimen ALCH-ABIM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7392ab43-9e23-4639-9554-a199303ba8fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABIM-NB1-A (Blood Derived Normal), aliquot ALCH-ABIM-NB1-A-1-0-D-A487-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7d80ac4-0bc9-480f-8f1f-3f012c69791f

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Intron 5, Nonsense Mutation 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 105/1119 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- ADGRF1 | c.1067C>G p.S356* | Nonsense Mutation (SNP) | VAF 31/346 reads (9%) | catalogued as COSV51944859; called by muse, mutect2
- CD34 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.618); catalogued as rs750812013, COSV104407306; called by muse, mutect2, varscan2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2
- EML6 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 28/896 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs962097491, COSV62866515; called by muse, mutect2
- NFE2L1 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 54/682 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761889543; called by muse, mutect2
- TRRAP | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 40/487 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV62841495; called by muse, mutect2
- ANKFN1 | c.1314A>G p.K438= | Splice Region (SNP) | VAF 48/496 reads (10%) | called by muse, mutect2
- APRT | c.473A>T p.E158V | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AR | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2
- FOXO6 | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- HEATR1 | c.4362T>G p.F1454L | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- HECTD1 | c.5729A>C p.K1910T | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.932); called by muse, mutect2
- IGKV1D-43 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 48/752 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2
- KIF1C | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- LAMB2 | c.4183G>T p.A1395S | Missense Mutation (SNP) | VAF 120/1115 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAPKAPK5 | c.1058A>T p.H353L | Missense Mutation (SNP) | VAF 44/544 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2
- MBTPS2 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 31/790 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- MFSD8 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 49/589 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPR1 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.14); called by muse, mutect2
- PCDH11X | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP2R5D | c.1513A>G p.M505V | Missense Mutation (SNP) | VAF 40/573 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- SHROOM1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZFHX4 | c.9776G>A p.G3259D | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- FLG | c.549A>G p.K183= | Silent (SNP) | VAF 60/735 reads (8%) | catalogued as rs765613413; called by muse, mutect2
- MST1R | c.1860C>A p.P620= | Silent (SNP) | VAF 40/450 reads (9%) | called by muse, mutect2
- MUC5AC | c.14271C>T p.S4757= | Silent (SNP) | VAF 50/678 reads (7%) | catalogued as rs377706617; called by muse, mutect2
- PRSS53 | c.954G>T p.L318= | Silent (SNP) | VAF 15/225 reads (7%) | catalogued as COSV54926008; called by muse, mutect2
- RAB34 | c.750C>T p.A250= | Silent (SNP) | VAF 96/1102 reads (9%) | called by muse, mutect2
- SLC39A4 | c.828G>A p.V276= (on ENST00000301305 / NM_001374839.1; = p.V251= on NM_017767.3) | Silent (SNP) | VAF 30/374 reads (8%) | called by muse, mutect2
- SYNM | c.375C>A p.G125= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1555482455; called by muse, mutect2
- TRIO | c.4950C>T p.D1650= | Silent (SNP) | VAF 14/365 reads (4%) | called by muse, mutect2
- VAMP7 | c.423C>A p.V141= | Silent (SNP) | VAF 15/366 reads (4%) | called by muse, mutect2
- COL9A1 | c.781-117G>C | Intron (SNP) | VAF 42/520 reads (8%) | called by muse, mutect2
- DDX27 | c.1887+57A>T | Intron (SNP) | VAF 57/581 reads (10%) | called by muse, mutect2
- FMR1 | c.*2044G>T | 3'UTR (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- KIRREL3 | c.56-119048G>A | Intron (SNP) | VAF 9/91 reads (10%) | called by muse, varscan2
- MAGED2 | c.1272-252C>T | Intron (SNP) | VAF 19/499 reads (4%) | catalogued as rs1252739651; called by muse, mutect2
- TAC4 | c.123+863C>T | Intron (SNP) | VAF 47/463 reads (10%) | catalogued as rs997284717, COSV58004302; called by muse, mutect2, varscan2
